Somatic mutation profile of tumor specimen MP2PRT-PAPUJY-TMP1-A (aliquot MP2PRT-PAPUJY-TMP1-A-1-0-D-A83N-36) from MP2PRT case MP2PRT-PAPUJY, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.5 years (1,294 days).
Specimen MP2PRT-PAPUJY-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2f81c9aa-a9ee-4a80-8a7a-84be49026c4a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPUJY-NM1-A (Blood Derived Cancer - Bone Marrow, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPUJY-NM1-A-1-0-D-A83N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ef059b04-84e8-4af2-b659-869021f756d5

The open-access MAF lists 9 somatic variants for this specimen: 8 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 5, In Frame Ins 3, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 105/289 reads (36%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.323); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ERG | c.1109A>G p.D370G (on ENST00000398919 / NM_001243428.1; = p.D346G on NM_004449.4) | Missense Mutation (SNP) | VAF 154/706 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55729043; called by muse, mutect2, varscan2
- FLT3 | c.1742_1743insTTCGGATCCACC p.V581_T582insSDPP | In Frame Ins (INS) | VAF 66/240 reads (28%) | catalogued as COSV54049725, COSV54052624, COSV54060068, COSV54063045; called by pindel, varscan2
- MARK2 | c.470G>A p.R157H | Missense Mutation (SNP) | VAF 78/226 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV59286957; called by muse, mutect2, varscan2
- RUNX1T1 | c.1372C>T p.R458C (on ENST00000265814 / NM_001198628.1; = p.R431C on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 141/367 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1381105316, COSV56138759; called by muse, mutect2, varscan2
- ABCA13 | c.14091G>C p.K4697N | Missense Mutation (SNP) | VAF 121/256 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.747); called by muse, mutect2, varscan2
- PURB | c.595_597dup p.E199dup | In Frame Ins (INS) | VAF 350/662 reads (53%) | called by mutect2, pindel, varscan2
- SLC22A7 | c.1544_1545insCTC p.T515_R516insS (on ENST00000372585 / NM_153320.2; = p.T513_R514insS on NM_006672.3) | In Frame Ins (INS) | VAF 95/285 reads (33%) | called by mutect2, pindel, varscan2
- IGKV1OR2-108 | c.330T>C p.C110= | Silent (SNP) | VAF 74/228 reads (32%) | called by muse, mutect2
